TCGA case TCGA-21-1077 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Fox Chase Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f516991c-5139-4b3e-b605-5a3d90688209

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 1,058 days (2.9 years).

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 64.4 years (23,523 days); Year of diagnosis: 2006; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 66.2 years (24,167 days); Days to diagnosis: 644 days (1.8 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS; Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 644 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,058 days (2.9 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 56; Tobacco smoking quit year: 1996.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-21-1077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-21-1077-01A-01-TS1: Section location: Top; Percent tumor nuclei: 85; Percent necrosis: 5.
  Slide TCGA-21-1077-01A-01-BS1: Section location: Bottom; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample TCGA-21-1077-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-21-1077-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Days to last known alive: 1057; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper.
- Follow-up form: New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: unknown treatment history.
- Prior malignancy: Subject has Hx of prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,058 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,058 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 644 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-21-1077-01): tumor purity 0.34, ploidy 2.64, whole-genome doublings 1 (call status: maf_call).
